Gene-level copy-number profile of tumor specimen TCGA-UY-A9PE-01A from TCGA case TCGA-UY-A9PE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 86.9 years (31,755 days).
Specimen TCGA-UY-A9PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.55293040-6c5e-452e-9638-70c81b069491.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c92e818c-3059-4c00-a452-b2e4b11728ba

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 304; copy number 2: 14,889; copy number 3: 17,978; copy number 4: 20,603; copy number 5: 1,883; copy number 6: 607; copy number 7: 753; copy number 8: 599; copy number 9: 947; copy number 10: 379; copy number 11: 213; copy number 12: 18; copy number 13: 120; copy number 14: 251; copy number 15: 1; copy number 16: 98; copy number 17: 39; copy number 19: 30; copy number 21: 10; copy number 22: 68; copy number 24: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PE-01A-11D-A38F-01): tumor purity 0.48, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,191 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,496,254–25,906,991, 49 genes, copy number 11 (within-gene range 6–11): RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, AL031432.4, AL031432.5, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A, RHCE, AL031284.1, MACO1, LDLRAP1, AL606491.1, MAN1C1, AL031280.1, SELENON, AL020996.2, AL020996.1, MTFR1L, AL020996.3, AUNIP, AL033528.2, PAQR7, Y_RNA, STMN1, SNRPFP2, AL033528.1, MIR3917.
- chr1:39,623,435–42,338,376, 85 genes, copy number 14–19 (broad region; genes not listed).
- chr1:71,395,943–73,355,253, 15 genes, copy number 12–17 (within-gene range 2–17): NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr1:158,327,951–158,686,715, 17 genes, copy number 14–15 (within-gene range 8–15): CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1.
- chr1:160,485,030–165,911,618, 147 genes, copy number 11–14 (within-gene range 8–14) (broad region; genes not listed).
- chr1:176,857,302–181,238,604, 84 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).
- chr2:164,213,539–166,390,771, 27 genes, copy number 10–13 (within-gene range 8–13): PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A.
- chr3:36,380,344–36,637,457, 2 genes, copy number 9: STAC, NBPF21P.
- chr3:36,826,819–36,945,057, 1 gene, copy number 9 (within-gene range 2–9): TRANK1.
- chr3:36,968,191–41,962,130, 113 genes, copy number 9 (broad region; genes not listed).
- chr3:51,395,867–53,347,586, 91 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr3:53,333,060–53,387,836, 2 genes, copy number 9: SNORD38C, AC112218.1.
- chr3:54,033,988–55,350,915, 12 genes, copy number 10: AC115282.2, CABYRP1, AC115282.1, CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1, AC092059.1, LINC02017, LINC02030, AC121764.2.
- chr5:34,656,328–34,832,612, 1 gene, copy number 17 (within-gene range 5–17): RAI14.
- chr5:34,837,549–35,230,487, 10 genes, copy number 17: AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1.
- chr5:42,972,624–43,412,391, 20 genes, copy number 13 (within-gene range 2–13): PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28.
- chr6:120,015,179–124,825,640, 44 genes, copy number 10 (within-gene range 7–10): MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1.
- chr6:127,632,958–129,710,177, 21 genes, copy number 9 (within-gene range 7–9): AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18.
- chr6:132,445,867–136,250,335, 87 genes, copy number 9 (broad region; genes not listed).
- chr6:145,296,545–145,964,423, 12 genes, copy number 11: AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH.
- chr7:38,257,879–38,311,808, 8 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:88,326,836–88,887,573, 1 gene, copy number 16 (within-gene range 4–24): AC090578.1.
- chr8:88,485,110–91,087,095, 29 genes, copy number 14–16: AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B.
- chr8:97,624,203–105,804,539, 177 genes, copy number 13–22 (within-gene range 4–22) (broad region; genes not listed).
- chr8:105,662,352–105,737,765, 3 genes, copy number 21: AC103853.1, AC103853.2, RPL12P24.
- chr10:1,957,589–16,295,858, 257 genes, copy number 9–10 (broad region; genes not listed).
- chr10:74,120,255–81,137,335, 143 genes, copy number 9–22 (broad region; genes not listed).
- chr10:121,410,916–126,421,879, 100 genes, copy number 10–14 (broad region; genes not listed).
- chr10:126,425,930–126,460,957, 1 gene, copy number 10: AL589787.1.
- chr11:49,558,546–50,298,452, 29 genes, copy number 9 (within-gene range 3–9): AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1.
- chr14:87,634,379–91,867,536, 87 genes, copy number 9–24 (broad region; genes not listed).
- chr17:31,563,768–31,831,750, 10 genes, copy number 10: RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P, GPR160P2, AC007923.1, AC004253.2.
- chr22:19,963,753–22,245,515, 161 genes, copy number 9–10 (broad region; genes not listed).
- chr22:23,132,730–27,920,134, 178 genes, copy number 10–11 (broad region; genes not listed).
- chr22:27,919,384–27,922,178, 4 genes, copy number 11: AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.
- chr22:29,436,534–33,145,861, 153 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr22:33,164,063–33,166,439, 1 gene, copy number 9: Z82198.2.
- chr22:33,704,786–34,651,862, 9 genes, copy number 12: SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2.

Autosomal genes at a single copy (total copy number 1): 304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
